Gene-level copy-number profile of tumor specimen TCGA-HU-A4GD-01A from TCGA case TCGA-HU-A4GD, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 56.7 years (20,700 days).
Specimen TCGA-HU-A4GD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.da1c7d8f-2d83-47d3-961e-2c3abcb8480d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4GD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/afc8cceb-3daa-41be-b672-d70d0c9f5b1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 932; copy number 2: 20,913; copy number 3: 10,476; copy number 4: 18,315; copy number 5: 5,437; copy number 6: 1,265; copy number 7: 916; copy number 8: 1,102; copy number 9: 195; copy number 10: 537; copy number 11: 72; copy number 13: 41; copy number 15: 5; copy number 39: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4GD-01A-11D-A253-01): tumor purity 0.82, ploidy 1.38, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:22,692,914–22,819,575, 2 genes (within-gene range 0–2): GBA3, CDC42P6.
- chr4:91,108,023–91,112,790, 1 gene: AC004054.1.
- chr13:31,960,325–31,961,946, 1 gene: AC002525.1.
- chr15:59,132,434–59,372,871, 5 genes (within-gene range 0–3): MYO1E, MIR2116, LDHAL6B, RNU4-80P, AC092756.1.
- chr17:17,810,399–17,837,011, 1 gene (within-gene range 0–2): SREBF1.
- chr17:17,843,511–17,972,422, 2 genes (within-gene range 0–3): TOM1L2, AC122129.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,017 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–152,843,983, 383 genes, copy number 6–10 (broad region; genes not listed).
- chr2:97,618,638–124,989,325, 467 genes, copy number 8–10 (broad region; genes not listed).
- chr3:93,843,764–100,993,515, 103 genes, copy number 5 (broad region; genes not listed).
- chr3:102,099,244–109,410,084, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:160,100,850–171,460,408, 140 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:171,815,586–178,007,779, 71 genes, copy number 5 (broad region; genes not listed).
- chr3:180,161,886–189,325,304, 210 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:190,852,737–193,378,820, 24 genes, copy number 5 (within-gene range 4–5): GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1.
- chr5:24,749,374–45,895,970, 314 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:126,257,921–130,574,112, 52 genes, copy number 5: PPP1R14BP5, AL356534.1, CENPW, MIR588, RNU6-200P, AL359535.1, PRELID1P1, RPS4XP9, AL035603.1, RSPO3, RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA.
- chr6:130,827,406–136,195,574, 110 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:136,335,714–137,494,394, 23 genes, copy number 5: AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1, MAP3K5, MAP3K5-AS1, RNA5SP219, AL121933.2, PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1, OLIG3.
- chr6:137,995,270–169,297,959, 504 genes, copy number 5–9 (broad region; genes not listed).
- chr6:170,088,022–170,738,536, 23 genes, copy number 5: AL603783.1, AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL031259.1, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr7:70,972–43,566,001, 750 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:44,125,752–53,036,925, 129 genes, copy number 5–6 (broad region; genes not listed).
- chr8:46,028,804–91,070,583, 663 genes, copy number 8–15 (broad region; genes not listed).
- chr8:91,205,485–145,066,685, 868 genes, copy number 7–8 (broad region; genes not listed).
- chr9:14,475–746,106, 19 genes, copy number 5: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.
- chr9:9,799,423–12,300,451, 15 genes, copy number 5: AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P.
- chr9:12,698,554–13,836,571, 12 genes, copy number 5 (within-gene range 3–5): LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235.
- chr9:20,999,509–21,278,619, 19 genes, copy number 6: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P.
- chr9:28,888,879–30,832,225, 13 genes, copy number 5: MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2.
- chr10:44,712–1,132,384, 22 genes, copy number 5 (within-gene range 4–5): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37.
- chr10:1,957,589–5,135,226, 58 genes, copy number 5: AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P, MANCR, LINC00705, AC018978.1, AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P.
- chr10:5,549,637–35,572,669, 507 genes, copy number 5–6 (broad region; genes not listed).
- chr10:35,896,874–42,475,349, 67 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:66,767–1,504,424, 30 genes, copy number 5: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942.
- chr12:122,271,432–124,088,594, 73 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:126,191,151–133,214,832, 212 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:27,456,470–41,786,931, 688 genes, copy number 5–7 (broad region; genes not listed).
- chr18:47,390–22,419,294, 416 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr18:23,134,564–29,361,963, 93 genes, copy number 5–6 (broad region; genes not listed).
- chr18:30,290,161–37,232,172, 113 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr19:27,638,483–33,382,686, 127 genes, copy number 5–9 (broad region; genes not listed).
- chr20:87,250–16,053,197, 291 genes, copy number 5–39 (within-gene range 2–39) (broad region; genes not listed).
- chr20:15,552,157–18,484,646, 58 genes, copy number 5–8 (within-gene range 4–8): AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192.
- chr20:25,284,915–64,313,132, 949 genes, copy number 5–7 (broad region; genes not listed).
- chr21:32,592,079–43,332,039, 250 genes, copy number 5–6 (broad region; genes not listed).
- chr21:45,593,654–46,665,124, 38 genes, copy number 5: LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 67. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
